Somatic mutation profile of cancer-model specimen HCM-WCMC-1344-C18-85A (3D Organoid; aliquot HCM-WCMC-1344-C18-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-1344-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 46.6 years (17,024 days).
Specimen HCM-WCMC-1344-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a57fcf3-0260-413e-a143-3a720d050059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1344-C18-12A (Saliva), aliquot HCM-WCMC-1344-C18-12A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d6b692b-9fb1-4b7c-a549-2267f068c4b2

The open-access MAF lists 1,604 somatic variants for this specimen: 1,205 protein-altering or splice-affecting, 337 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 807, Silent 337, Frame Shift Del 273, Frame Shift Ins 67, Intron 35, Nonsense Mutation 33, 3'UTR 9, Splice Region 9, In Frame Del 8, 5'Flank 5, 3'Flank 5, 5'UTR 5.

Variants (750 of 1,604; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 31/289 reads (11%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 242/322 reads (75%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ACO2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 247/538 reads (46%) | catalogued as rs387907389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 237/492 reads (48%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- C19orf12 | c.205G>A p.G69R (on ENST00000392278 / NM_001031726.3; = p.G58R on NM_031448.6) | Missense Mutation (SNP) | VAF 184/322 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs515726205, CM118380, COSV100080664, COSV60364177; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 447/447 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 222/452 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HKDC1 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 226/472 reads (48%) | catalogued as rs759709025; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 58/436 reads (13%) | catalogued as rs121918672, CM021700, CM055552; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCND3 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 219/489 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs786205867, CM124831; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 156/404 reads (39%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ1 | c.1343del p.P448Qfs*18 | Frame Shift Del (DEL) | VAF 299/684 reads (44%) | catalogued as rs397508087, CM097219; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LZTR1 | c.27dup p.Q10Afs*24 | Frame Shift Ins (INS) | VAF 229/466 reads (49%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 108/222 reads (49%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as rs312262810, CM010945, COSV60794563; ClinVar: pathogenic; called by muse, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 99/374 reads (26%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by pindel, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 112/303 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PKD2 | c.203del p.P68Rfs*49 | Frame Shift Del (DEL) | VAF 265/698 reads (38%) | catalogued as rs1187336837; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 84/418 reads (20%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 345/700 reads (49%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARS1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs765846298, COSV55747318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.1671del p.E558Rfs*3 (on ENST00000614293; = p.E528Rfs*3 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 261/592 reads (44%) | catalogued as COSV55803541; called by mutect2, pindel, varscan2
- ABHD18 | c.699G>A p.T233= (on ENST00000398965 / NM_001039717.2; = p.T106= on NM_025097.2 and 10 other RefSeq transcripts) | Splice Region (SNP) | VAF 149/288 reads (52%) | catalogued as rs201083117; called by muse, mutect2, varscan2
- ACAD8 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 225/486 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1278727402; called by muse, mutect2, varscan2
- ACP6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 175/331 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782324354; called by muse, mutect2, varscan2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2, varscan2
- ADAD2 | c.958del p.Q320Sfs*57 (on ENST00000315906 / NM_001145400.2; = p.Q402Sfs*57 on NM_139174.4) | Frame Shift Del (DEL) | VAF 211/731 reads (29%) | catalogued as COSV99235736; called by mutect2, pindel, varscan2
- ADAM10 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53052302; called by muse, mutect2, varscan2
- ADCY3 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333561857, COSV53164277; called by muse, mutect2, varscan2
- ADCY9 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 160/505 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV53578332; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 112/262 reads (43%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 293/626 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs538552021, COSV66925660; called by muse, mutect2, varscan2
- ADGRB1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 430/832 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1201951121; called by muse, mutect2, varscan2
- ADGRV1 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 243/495 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.312); catalogued as COSV67992605; called by muse, mutect2, varscan2
- ADGRV1 | c.11674C>T p.R3892W | Missense Mutation (SNP) | VAF 251/560 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs766913299, COSV67979727; called by muse, mutect2
- ADH1A | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 195/382 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760558326; called by muse, mutect2, varscan2
- ADNP2 | c.2797G>A p.V933I | Missense Mutation (SNP) | VAF 220/466 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs368537313; called by muse, mutect2, varscan2
- ADPRHL1 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 80/1047 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs1011283156; called by muse, mutect2
- ADRA2C | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 377/686 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1213435958; called by muse, mutect2, varscan2
- AFAP1 | c.1552del p.V518Wfs*13 | Frame Shift Del (DEL) | VAF 178/371 reads (48%) | catalogued as COSV61797323; called by mutect2, varscan2
- AGBL5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 222/457 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747996062, COSV59938069; called by muse, mutect2, varscan2
- AL121899.2 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 49/391 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs760209949; called by muse, mutect2, varscan2
- ALDH2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 317/589 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1453018126, COSV55666998; called by muse, varscan2
- ALDH5A1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 230/459 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs755160772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH7A1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs746212816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 196/399 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs777313140; called by muse, mutect2, varscan2
- ALPP | c.976del p.R326Afs*25 | Frame Shift Del (DEL) | VAF 141/1166 reads (12%) | catalogued as rs752094035; called by pindel, varscan2
- AMBRA1 | c.3787G>A p.A1263T (on ENST00000458649 / NM_001367468.1; = p.A1173T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 285/591 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs964199125, COSV100095536; called by muse, mutect2, varscan2
- ANKRD10 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 214/638 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57444860; called by muse, mutect2, varscan2
- ANKRD11 | c.4456C>T p.R1486W | Missense Mutation (SNP) | VAF 209/606 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs189656772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD13B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 212/422 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs752789986; called by muse, mutect2, varscan2
- ANKRD36 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1559196677; called by muse, mutect2, varscan2
- ANKRD36C | c.4764dup p.Q1589Tfs*11 | Frame Shift Ins (INS) | VAF 156/362 reads (43%) | catalogued as rs200875477; called by mutect2, varscan2
- ANXA10 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 224/439 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV63738514; called by muse, mutect2
- ANXA11 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 178/380 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs760637842; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 112/402 reads (28%) | catalogued as rs546686089; called by mutect2, varscan2
- ARAP1 | c.932C>T p.A311V (on ENST00000393609 / NM_001040118.2; = p.A66V on NM_015242.4) | Missense Mutation (SNP) | VAF 280/602 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201444185, CM142293, COSV61993696; called by muse, mutect2, varscan2
- ARHGAP23 | c.265del p.R89Gfs*15 | Frame Shift Del (DEL) | VAF 144/579 reads (25%) | catalogued as rs1166703552; called by mutect2, pindel, varscan2
- ARHGDIG | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 152/476 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201950145; called by muse, mutect2, varscan2
- ARHGEF10L | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 171/356 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs750552676, COSV51440978; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 238/623 reads (38%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID3B | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 241/468 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs145901163; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 295/482 reads (61%) | catalogued as rs965020534; called by mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 372/990 reads (38%) | catalogued as rs768611141; called by pindel, varscan2
- ATG4A | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs140831275, COSV58968326; called by muse, mutect2, varscan2
- ATM | c.5077G>T p.D1693Y | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53735089; called by muse, mutect2
- ATP9A | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1410897131; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 198/556 reads (36%) | catalogued as rs1288664341; called by pindel, varscan2
- AUTS2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 68/594 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs749176066, COSV100719704, COSV61385358; called by muse, mutect2, varscan2
- B3GAT2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 195/372 reads (52%) | catalogued as rs750513549, COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2, varscan2
- B4GALT7 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567512466; called by muse, varscan2
- BACH2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 87/571 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs375103380, COSV57612203; called by muse, mutect2, varscan2
- BAHCC1 | c.7004C>G p.A2335G | Missense Mutation (SNP) | VAF 343/733 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV57031339; called by muse, mutect2, varscan2
- BARHL2 | c.376dup p.Q126Pfs*20 | Frame Shift Ins (INS) | VAF 84/780 reads (11%) | catalogued as rs747119215; called by mutect2, varscan2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 139/452 reads (31%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BTBD6 | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 34/634 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59266414; called by muse, mutect2
- BTD | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 267/514 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs757604137; called by muse, mutect2, varscan2
- BUB1 | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 154/315 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs1449377689; called by muse, mutect2, varscan2
- C15orf39 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 357/695 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs201514875, COSV100641353, COSV62297986; called by muse, mutect2, varscan2
- C16orf96 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 209/414 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs950903112; called by muse, mutect2
- C2CD3 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 191/499 reads (38%) | catalogued as rs1406007301, CD164515; called by mutect2, pindel, varscan2
- C2orf69 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100178932; called by muse, mutect2, varscan2
- CACNA1B | c.108del p.L37Cfs*64 | Frame Shift Del (DEL) | VAF 182/736 reads (25%) | catalogued as rs1474416938; called by mutect2, pindel, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 165/458 reads (36%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAND2 | c.1768C>T p.R590W (on ENST00000456430 / NM_001162499.2; = p.R497W on NM_012298.3) | Missense Mutation (SNP) | VAF 291/601 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1392836335, COSV55992521; called by muse, mutect2, varscan2
- CAPN13 | c.1282dup p.S428Ffs*12 | Frame Shift Ins (INS) | VAF 147/348 reads (42%) | catalogued as rs1479139254; called by mutect2, varscan2
- CAPN3 | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 136/411 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1277684622; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 169/423 reads (40%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARS2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 214/718 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759804272, COSV57285563; called by muse, mutect2, varscan2
- CASD1 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 157/387 reads (41%) | catalogued as rs1228214882, COSV51972279; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 82/629 reads (13%) | catalogued as COSV100050703; called by mutect2, pindel, varscan2
- CATSPERG | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 168/280 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs547897343; called by muse, mutect2, varscan2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 38/390 reads (10%) | catalogued as rs368765497; called by mutect2, pindel
- CCDC124 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 351/647 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759811844; called by muse, mutect2, varscan2
- CCDC141 | c.2906C>A p.S969Y | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV99835970; called by muse, mutect2, varscan2
- CCDC9 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 260/557 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs769602417; called by muse, mutect2, varscan2
- CD200R1 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 107/438 reads (24%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.949); catalogued as rs760995230; called by muse, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 154/409 reads (38%) | catalogued as rs762805003; called by mutect2, varscan2
- CD93 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 165/518 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV55664430; called by mutect2, varscan2
- CDC42EP1 | c.289dup p.R97Pfs*78 | Frame Shift Ins (INS) | VAF 184/579 reads (32%) | catalogued as rs762035931; called by mutect2, varscan2
- CDH23 | c.5455C>A p.L1819M | Missense Mutation (SNP) | VAF 214/494 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV99822080; called by muse, mutect2
- CDH24 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 231/535 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746379911, COSV57458875; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1594C>T p.R532C (on ENST00000357886 / NM_001365728.1; = p.R518C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751785823; called by muse, mutect2, varscan2
- CDR2L | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 361/686 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1259917122, COSV104398160; called by muse, mutect2, varscan2
- CDYL | c.298G>A p.V100M (on ENST00000328908 / NM_001368125.1; = p.V46M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/493 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs145622412; called by muse, mutect2, varscan2
- CECR2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs368613674, COSV52849609, COSV99379044; called by muse, varscan2
- CELF6 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 303/610 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs202213817; called by muse, mutect2, varscan2
- CELSR2 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 269/564 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs1037932407; called by muse, mutect2, varscan2
- CELSR2 | c.8767C>T p.H2923Y | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1291388409, COSV54772597; called by muse, mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 120/301 reads (40%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP170B | c.3499C>T p.R1167C (on ENST00000453495; = p.R1096C on NM_015005.3) | Missense Mutation (SNP) | VAF 351/697 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866933875, COSV69024975; called by muse, mutect2, varscan2
- CEP170B | c.3830G>A p.R1277H (on ENST00000453495; = p.R1206H on NM_015005.3) | Missense Mutation (SNP) | VAF 84/675 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1397878262, COSV52045177, COSV99229799; called by muse, mutect2, varscan2
- CEP295 | c.660del p.K220Nfs*29 | Frame Shift Del (DEL) | VAF 165/411 reads (40%) | catalogued as COSV57359099; called by mutect2, pindel, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 128/272 reads (47%) | catalogued as rs751492244; called by mutect2, varscan2
- CFP | c.146del p.G49Vfs*43 | Frame Shift Del (DEL) | VAF 26/296 reads (9%) | catalogued as rs749541242; called by mutect2, pindel
- CHD4 | c.1895G>A p.R632Q (on ENST00000357008 / NM_001363606.2; = p.R645Q on NM_001273.5) | Missense Mutation (SNP) | VAF 149/333 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1356961959; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 129/297 reads (43%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 196/422 reads (46%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA9 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 58/526 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.429); catalogued as rs1560319689; called by muse, mutect2, varscan2
- CHST1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 75/566 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV57323520; called by muse, mutect2, varscan2
- CLCNKB | c.1395del p.Y466Mfs*13 | Frame Shift Del (DEL) | VAF 74/270 reads (27%) | catalogued as rs762878606; called by mutect2, pindel, varscan2
- CLMN | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 131/378 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.485); catalogued as rs145504462, COSV54183653; called by muse, mutect2, varscan2
- CLPX | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs1163453717; called by muse, mutect2, varscan2
- CMTM2 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 194/354 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1418049635; called by muse, mutect2, varscan2
- CNOT3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 393/826 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs372481652; called by muse, mutect2, varscan2
- CNTN5 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 189/373 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV54321735; called by muse, mutect2, varscan2
- CNTROB | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 172/522 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs748617832; called by muse, varscan2
- COL11A1 | c.1735del p.R579Gfs*54 | Frame Shift Del (DEL) | VAF 137/335 reads (41%) | catalogued as COSV62195334; called by mutect2, pindel, varscan2
- COL15A1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 192/666 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV99055709; called by muse, mutect2, varscan2
- COLEC12 | c.1614del p.G539Afs*107 | Frame Shift Del (DEL) | VAF 72/674 reads (11%) | catalogued as rs766571982, COSV101232185; called by mutect2, pindel, varscan2
- COPS5 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474235; called by muse, mutect2, varscan2
- CPSF1 | c.4315G>A p.V1439I | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs1554861915, COSV58232045; called by muse, mutect2
- CPVL | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761706669, COSV55306539; called by muse, mutect2, varscan2
- CRTC1 | c.1713dup p.S572Qfs*4 | Frame Shift Ins (INS) | VAF 134/315 reads (43%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBB1 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 77/590 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53233671; called by muse, mutect2, varscan2
- CSMD1 | c.5299G>A p.E1767K (on ENST00000520002; = p.E1766K on NM_033225.6) | Missense Mutation (SNP) | VAF 226/465 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1305727463, COSV59345424; called by muse, mutect2, varscan2
- CSMD2 | c.6538+1G>C p.X2180_splice | Splice Site (SNP) | VAF 178/341 reads (52%) | catalogued as COSV53912091; called by muse, mutect2
- CTCF | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 180/559 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1305124662; called by muse, mutect2, varscan2
- CTIF | c.1729A>C p.S577R | Missense Mutation (SNP) | VAF 218/545 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1195047290; called by muse, mutect2, varscan2
- CTSH | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 110/345 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs201782561, COSV54985005; called by muse, mutect2, varscan2
- CUEDC2 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 256/537 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs753914938; called by muse, mutect2, varscan2
- CUL3 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs759758641, COSV52362153; called by muse, varscan2
- CUX2 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 377/732 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1239347097; called by muse, mutect2, varscan2
- CYP4V2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 296/594 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs762474840, COSV66507141; called by muse, mutect2
- CYP51A1 | c.1026dup p.C343Mfs*19 | Frame Shift Ins (INS) | VAF 152/334 reads (46%) | catalogued as rs746385504; called by mutect2, varscan2
- DAO | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566264618, COSV57323592; called by muse, mutect2, varscan2
- DAP | c.215del p.P72Rfs*148 | Frame Shift Del (DEL) | VAF 137/363 reads (38%) | catalogued as rs777516488; called by mutect2, pindel, varscan2
- DBH | c.1781del p.P594Hfs*87 | Frame Shift Del (DEL) | VAF 252/762 reads (33%) | catalogued as COSV67549641; called by mutect2, pindel, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 63/249 reads (25%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 186/410 reads (45%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 54/446 reads (12%) | catalogued as rs766714372; called by mutect2, varscan2
- DEAF1 | c.56_88del p.V19_A29del | In Frame Del (DEL) | VAF 22/206 reads (11%) | catalogued as rs1267034467; called by mutect2, pindel
- DEPDC7 | c.181C>T p.R61* (on ENST00000241051 / NM_001077242.2; = p.R52* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 203/408 reads (50%) | catalogued as rs1326267387; called by muse, mutect2, varscan2
- DGCR8 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 243/501 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs778992846; called by muse, mutect2, varscan2
- DHX33 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753632223, COSV56579753; called by muse, mutect2, varscan2
- DIDO1 | c.6659G>A p.S2220N | Missense Mutation (SNP) | VAF 299/636 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1469304233; called by muse, mutect2, varscan2
- DLGAP1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 300/606 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs142650515; called by muse, mutect2, varscan2
- DMXL2 | c.8756del p.G2919Vfs*48 | Frame Shift Del (DEL) | VAF 186/468 reads (40%) | catalogued as COSV51847581; called by mutect2, pindel, varscan2
- DNAH2 | c.7024C>T p.R2342* | Nonsense Mutation (SNP) | VAF 209/431 reads (48%) | catalogued as rs749486150, COSV101209042; called by muse, mutect2, varscan2
- DNAH3 | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 55/445 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs964016861, COSV54508424; called by muse, mutect2, varscan2
- DNHD1 | c.11059C>T p.P3687S | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs866863010; called by muse, mutect2, varscan2
- DNMT3L | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 299/595 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1265705625; called by muse, mutect2, varscan2
- DOCK1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.184); catalogued as rs776990526; called by muse, varscan2
- DPF2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 177/422 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs994854120, COSV52890510; called by muse, mutect2, varscan2
- DRD5 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 216/468 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576727; called by muse, varscan2
- DRD5 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 226/424 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs143535200; called by muse, varscan2
- DSCAML1 | c.5347C>T p.R1783W (on ENST00000321322; = p.R1723W on NM_020693.4) | Missense Mutation (SNP) | VAF 163/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454536192, COSV100356033; called by muse, mutect2, varscan2
- DUOX2 | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 128/442 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1346046235; called by muse, mutect2, varscan2
- DUSP16 | c.1633G>C p.A545P | Missense Mutation (SNP) | VAF 212/439 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99963406; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 96/366 reads (26%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 151/301 reads (50%) | catalogued as rs772082432; called by mutect2, varscan2
- DZANK1 | c.1005del p.T336Pfs*55 (on ENST00000262547 / NM_001099407.1; = p.T137Pfs*55 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 115/464 reads (25%) | catalogued as rs775441744; called by mutect2, pindel, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 130/438 reads (30%) | catalogued as rs771114476; called by mutect2, varscan2
- EBF2 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 92/318 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs775802221; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 98/306 reads (32%) | catalogued as rs760813779; called by mutect2, varscan2
- EFNA1 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 188/578 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1205239967; called by muse, mutect2, varscan2
- EIF2B1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 186/398 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1245638011, COSV53015723; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 260/540 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314697052; called by muse, varscan2
- ELMOD2 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 116/403 reads (29%) | catalogued as rs750143144; called by muse, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 193/391 reads (49%) | catalogued as rs766700925; called by mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 176/660 reads (27%) | catalogued as COSV53155402; called by pindel, varscan2
- EMILIN1 | c.1386del p.R463Gfs*98 | Frame Shift Del (DEL) | VAF 72/572 reads (13%) | catalogued as rs753533275; called by pindel, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 108/314 reads (34%) | catalogued as rs746682537; called by mutect2, varscan2
- EP400 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 249/527 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764793090, COSV100201239; called by muse, mutect2, varscan2
- EPG5 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 216/444 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as rs201678945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPX | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 228/470 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342884566; called by muse, mutect2, varscan2
- EPX | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs148158670, COSV99836648; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 105/390 reads (27%) | catalogued as rs753821453; called by mutect2, varscan2
- ESRRB | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 91/679 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412199395, COSV55058254; called by muse, mutect2, varscan2
- FASTKD2 | c.74del p.F25Sfs*10 | Frame Shift Del (DEL) | VAF 194/472 reads (41%) | catalogued as COSV52697899; called by mutect2, pindel, varscan2
- FAT1 | c.2906A>G p.H969R | Missense Mutation (SNP) | VAF 138/445 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs201568112; called by muse, mutect2, varscan2
- FAT3 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 167/348 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs780430076; called by muse, mutect2, varscan2
- FAT3 | c.8866G>A p.V2956I | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776741179, COSV53120539; called by muse, varscan2
- FAT4 | c.4471C>A p.L1491I | Missense Mutation (SNP) | VAF 65/532 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs374317713; called by muse, mutect2, varscan2
- FBXO30 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 96/350 reads (27%) | catalogued as COSV52790796; called by muse, mutect2, varscan2
- FGFR1 | c.1615G>A p.G539R (on ENST00000447712 / NM_023110.3; = p.G537R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201158796, COSV58335333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGFR4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 288/645 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.7); catalogued as rs754036845, COSV52811197; called by muse, mutect2
- FLOT2 | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as rs1407716569; called by muse, mutect2, varscan2
- FLT3LG | c.351dup p.S118Qfs*130 (on ENST00000594009 / NM_001204503.2; = p.S118Qfs*189 on NM_001459.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 104/285 reads (36%) | catalogued as rs769482947; called by mutect2, varscan2
- FOXF1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 319/575 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747243553; called by muse, mutect2, varscan2
- FOXF1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 180/594 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1403431841; called by muse, mutect2, varscan2
- FOXN3 | c.287dup p.S97Ifs*6 | Frame Shift Ins (INS) | VAF 200/432 reads (46%) | catalogued as rs760347049; called by mutect2, varscan2
- FOXRED2 | c.790A>G p.N264D | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs898020623; called by muse, mutect2
- GALNT18 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 188/386 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57158369; called by muse, varscan2
- GALNT9 | c.1804C>T p.R602W (on ENST00000328957 / NM_001122636.2; = p.R236W on NM_021808.3) | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs747853052, COSV61100626, COSV61102717; called by muse, mutect2, varscan2
- GATA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 264/778 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); catalogued as rs761929509, CD043939, COSV60519846; called by muse, mutect2, varscan2
- GDPD5 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61127014; called by muse, mutect2, varscan2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 168/407 reads (41%) | catalogued as rs763284415; called by mutect2, pindel, varscan2
- GFOD1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 58/591 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs371884277, COSV101015054; called by muse, mutect2, varscan2
- GFRA3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 146/396 reads (37%) | catalogued as rs1371452874; called by muse, varscan2
- GJA8 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 269/583 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs372038463; called by muse, mutect2, varscan2
- GNAQ | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 54/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54107922; called by muse, mutect2
- GOLGA4 | c.4520G>A p.S1507N | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV62712934; called by muse, mutect2, varscan2
- GPLD1 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 166/353 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs772564077; called by muse, mutect2, varscan2
- GPR160 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 154/342 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573747285, COSV63472804; called by muse, mutect2, varscan2
- GPR179 | c.2873C>T p.T958I (on ENST00000621958; = p.T957I on NM_001004334.4) | Missense Mutation (SNP) | VAF 110/817 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs1409996456; called by muse, mutect2, varscan2
- GPT | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 265/547 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1379453991; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 32/268 reads (12%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2B | c.3958C>T p.R1320C | Missense Mutation (SNP) | VAF 75/545 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74206011; called by muse, mutect2, varscan2
- GRIP2 | c.2855C>A p.P952Q (on ENST00000619221; = p.P855Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); catalogued as COSV56121008; called by muse, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 142/362 reads (39%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- HADHA | c.2219A>G p.Y740C | Missense Mutation (SNP) | VAF 169/487 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66108303; called by muse, mutect2, varscan2
- HCFC2 | c.25T>C p.W9R | Missense Mutation (SNP) | VAF 155/498 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57559067; called by muse, mutect2, varscan2
- HDAC1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1265388078, COSV61482059; called by muse, mutect2, varscan2
- HDAC11 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 262/479 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs142419489; called by muse, mutect2, varscan2
- HDX | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 303/305 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1316677076; called by muse, mutect2, varscan2
- HEATR5A | c.5426G>A p.R1809Q | Missense Mutation (SNP) | VAF 165/333 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs559824863, COSV101119455; called by muse, mutect2, varscan2
- HEATR5B | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 250/499 reads (50%) | catalogued as rs1348209192; called by muse, mutect2, varscan2
- HECTD3 | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 220/582 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs753154497, COSV55799019; called by muse, varscan2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 80/648 reads (12%) | catalogued as rs745497383; called by mutect2, varscan2
- HEPH | c.1667C>T p.P556L (on ENST00000343002; = p.P289L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297747549, COSV57968760; called by muse, mutect2
- HERC1 | c.10714C>A p.R3572S | Missense Mutation (SNP) | VAF 172/359 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.131); catalogued as COSV101496883; called by muse, mutect2, varscan2
- HIVEP3 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 290/588 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs762301632, COSV56010507; called by muse, mutect2, varscan2
- HMOX1 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV53340676; called by muse, mutect2, varscan2
- HSD17B1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 214/471 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778944174; called by muse, mutect2, varscan2
- HSPG2 | c.8212G>A p.V2738M | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144862631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUS1B | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 244/584 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs757961681, COSV100033535; called by muse, mutect2
- ICE2 | c.1899dup p.P634Tfs*7 | Frame Shift Ins (INS) | VAF 163/379 reads (43%) | catalogued as rs773511663; called by mutect2, varscan2
- IFITM5 | c.95del p.P32Rfs*6 | Frame Shift Del (DEL) | VAF 79/707 reads (11%) | catalogued as rs774773661; called by mutect2, pindel, varscan2
- IGHA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 184/432 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782085693; called by muse, varscan2
- IGSF9B | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 243/512 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58064601; called by muse, mutect2, varscan2
- INTS1 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs375215357; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 298/628 reads (47%) | catalogued as rs761880048; called by mutect2, varscan2
- ISL1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 160/603 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57933994; called by muse, mutect2, varscan2
- ITGB5 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 64/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56146860; called by muse, mutect2, varscan2
- IVL | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs760318427; called by muse, mutect2, varscan2
- KANK2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 318/648 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs370098562; called by muse, mutect2, varscan2
- KCNAB3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 285/607 reads (47%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.323); catalogued as COSV58050819; called by muse, varscan2
- KCND2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 191/421 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576645; called by muse, mutect2, varscan2
- KCNG1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 283/572 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs761694072, COSV65367996; called by muse, mutect2, varscan2
- KCNG2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 230/450 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161088582; called by muse, varscan2
- KCNU1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765942865, COSV67755264; called by muse, mutect2, varscan2
- KIAA1109 | c.7613C>T p.A2538V | Missense Mutation (SNP) | VAF 222/466 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.265); catalogued as rs368105993; called by muse, mutect2, varscan2
- KIAA1522 | c.947G>A p.R316H (on ENST00000373480 / NM_001198972.2; = p.R375H on NM_020888.3) | Missense Mutation (SNP) | VAF 334/644 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1353411253, COSV53866155; called by muse, mutect2, varscan2
- KIAA2012 | c.2523del p.K841Nfs*2 | Frame Shift Del (DEL) | VAF 139/362 reads (38%) | catalogued as rs760609491; called by mutect2, varscan2
- KIF13A | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1478438447, COSV52462135; called by muse, mutect2, varscan2
- KIF20B | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755790468, COSV53310332; called by muse, mutect2, varscan2
- KIFC1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 336/691 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746419470; called by muse, mutect2, varscan2
- KLF16 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 181/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464155965, COSV51736425; called by muse, mutect2, varscan2
- KLHDC4 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 208/394 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV54508110; called by muse, mutect2, varscan2
- KLHL30 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 224/445 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.051); catalogued as rs778622350; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 88/264 reads (33%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.2372_2374del p.K791del | In Frame Del (DEL) | VAF 112/479 reads (23%) | catalogued as rs1485125839; called by pindel, varscan2
- KNL1 | c.1114G>A p.A372T (on ENST00000346991 / NM_170589.5; = p.A346T on NM_144508.5) | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs1014837740; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 280/428 reads (65%) | catalogued as rs764099275; called by mutect2, varscan2
- KPRP | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 354/708 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1463856931, COSV64222717; called by muse, mutect2
- KRT73 | c.158del p.G53Vfs*65 | Frame Shift Del (DEL) | VAF 176/668 reads (26%) | catalogued as rs745616492, COSV99988806; called by mutect2, pindel, varscan2
- KRT76 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 313/654 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372674456; called by muse, varscan2
- KRTAP4-3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 255/640 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs1442367115, COSV101194142; called by muse, varscan2
- KSR2 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 206/449 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs376679729, COSV56667955; called by muse, mutect2, varscan2
- LAMA2 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 127/440 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101370793, COSV70347217; called by muse, mutect2
- LAMA5 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 289/637 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756189022, COSV53361493; called by muse, mutect2, varscan2
- LAMB2 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 246/498 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs376290063; called by muse, varscan2
- LAMB4 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52713455, COSV52715412; called by muse, mutect2, varscan2
- LCORL | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 219/549 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as rs1314757441, COSV58834458; called by muse, mutect2, varscan2
- LDLRAP1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 101/387 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs1431472138; called by muse, mutect2, varscan2
- LETM2 | c.1424C>T p.A475V (on ENST00000379957 / NM_001286819.2; = p.A380V on NM_144652.3) | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1480461184; called by muse, mutect2, varscan2
- LGI4 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 419/829 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV59535444; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 52/354 reads (15%) | catalogued as rs748571616; called by mutect2, varscan2
- LIMA1 | c.1605dup p.T536Hfs*2 | Frame Shift Ins (INS) | VAF 177/445 reads (40%) | catalogued as rs1400710960; called by mutect2, pindel, varscan2
- LMAN1L | c.177C>T p.D59= | Splice Region (SNP) | VAF 135/342 reads (39%) | catalogued as rs1225983970; called by muse, mutect2, varscan2
- LONRF2 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 119/298 reads (40%) | catalogued as rs771704410, COSV66540256; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 366/752 reads (49%) | catalogued as COSV100540885; called by mutect2, varscan2
- LRGUK | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 178/379 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs750348362, COSV53634666; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 210/426 reads (49%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC27 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 219/453 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs769773519, COSV59812433; called by muse, mutect2, varscan2
- LRRC3B | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV67521134; called by muse, mutect2, varscan2
- LRRC57 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 190/377 reads (50%) | catalogued as COSV52999431; called by muse, mutect2, varscan2
- LRRC70 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs146092308; called by muse, mutect2, varscan2
- LRRC74B | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 232/446 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs747155313, COSV61187723; called by muse, mutect2, varscan2
- LRRK1 | c.4231G>A p.G1411R | Missense Mutation (SNP) | VAF 269/513 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211781027, COSV52624132; called by muse, mutect2, varscan2
- MACF1 | c.8771T>A p.I2924N | Missense Mutation (SNP) | VAF 108/258 reads (42%) | catalogued as COSV57105138, COSV57124948; called by muse, mutect2, varscan2
- MACIR | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 142/262 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); catalogued as rs1554237601; called by muse, mutect2, varscan2
- MACROH2A2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 249/535 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs779007856; called by muse, mutect2, varscan2
- MAGEL2 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 270/541 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs370022000, COSV100045952; called by muse, mutect2, varscan2
- MAMDC4 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 54/483 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs758902427; called by muse, mutect2, varscan2
- MAN2A1 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 77/561 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV99812231; called by muse, mutect2, varscan2
- MAP2K3 | c.295G>A p.V99M (on ENST00000342679 / NM_145109.3; = p.V70M on NM_002756.4) | Missense Mutation (SNP) | VAF 118/482 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1156837659; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 240/500 reads (48%) | catalogued as rs765962881; called by mutect2, varscan2
- MARF1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 260/573 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs369224578; called by muse, mutect2, varscan2
- MATN4 | c.1450C>T p.R484W (on ENST00000372754; = p.R443W on NM_003833.4) | Missense Mutation (SNP) | VAF 296/623 reads (48%) | PolyPhen probably damaging (1); catalogued as rs202220426; called by muse, mutect2, varscan2
- MAZ | c.70del p.V24Wfs*5 | Frame Shift Del (DEL) | VAF 61/558 reads (11%) | catalogued as rs1484448771; called by mutect2, pindel, varscan2
- MDGA1 | c.1745T>C p.L582P | Missense Mutation (SNP) | VAF 109/811 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs950618708, COSV51792499; called by muse, mutect2, varscan2
- MDN1 | c.15772C>T p.R5258* | Nonsense Mutation (SNP) | VAF 189/450 reads (42%) | catalogued as rs1311244151; called by muse, mutect2, varscan2
- MEF2A | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs754720431, COSV57536906; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 72/553 reads (13%) | catalogued as rs759225724; called by mutect2, varscan2
- MEGF6 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 217/444 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1019813107; called by muse, varscan2
- MEI4 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 167/341 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs539939524; called by muse, mutect2, varscan2
- METRNL | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 286/820 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs749165658, COSV60761267; called by muse, mutect2
- METTL2B | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 276/568 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773126594; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 513/791 reads (65%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIDEAS | c.106dup p.Q36Pfs*33 | Frame Shift Ins (INS) | VAF 76/597 reads (13%) | catalogued as rs760940567; called by mutect2, varscan2
- MIIP | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 55/499 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV52428605; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 275/436 reads (63%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MNAT1 | c.315T>C p.I105= | Splice Region (SNP) | VAF 31/187 reads (17%) | catalogued as rs755499243; called by muse, mutect2, varscan2
- MOAP1 | c.37A>G p.M13V | Missense Mutation (SNP) | VAF 244/506 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as rs767631342, COSV52092503; called by muse, varscan2
- MOB3C | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 280/548 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV54718645; called by muse, mutect2, varscan2
- MRGPRX4 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs763132057; called by mutect2, varscan2
- MROH1 | c.3262C>T p.L1088F | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1460797214; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 168/398 reads (42%) | catalogued as rs756600463; called by mutect2, varscan2
- MST1R | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771218531; called by muse, mutect2, varscan2
- MTMR12 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.67); catalogued as rs1259407263; called by muse, mutect2, varscan2
- MTURN | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs138966019; called by muse, mutect2, varscan2
- MUC1 | c.2822del p.P941Qfs*170 (on ENST00000611571 / NM_001371720.1; = p.P154Qfs*170 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 156/492 reads (32%) | catalogued as rs1203356608; called by mutect2, pindel, varscan2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 63/524 reads (12%) | catalogued as COSV67467225; called by mutect2, pindel, varscan2
- MUC16 | c.12058G>A p.V4020I | Missense Mutation (SNP) | VAF 188/396 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as rs373276168; called by muse, mutect2
- MUC16 | c.4682C>T p.T1561M | Missense Mutation (SNP) | VAF 226/441 reads (51%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs199772369; called by muse, mutect2, varscan2
- MUC4 | c.15613C>T p.R5205W (on ENST00000463781 / NM_018406.7; = p.R969W on NM_004532.6) | Missense Mutation (SNP) | VAF 267/582 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs780841763; called by muse, mutect2, varscan2
- MYBL2 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 150/441 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1022966588; called by muse, mutect2, varscan2
- MYBPHL | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779957053; called by muse, mutect2, varscan2
- MYC | c.1316C>T p.A439V (on ENST00000377970; = p.A454V on NM_002467.6) | Missense Mutation (SNP) | VAF 157/276 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV52372769; called by muse, mutect2, varscan2
- MYH7 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 244/532 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV62518092; called by muse, mutect2, varscan2
- N4BP3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 143/445 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs535517572; called by muse, mutect2, varscan2
- NAGA | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 237/492 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs367803688; called by muse, mutect2, varscan2
- NAV2 | c.3283G>A p.A1095T (on ENST00000396087 / NM_001244963.2; = p.A1072T on NM_145117.5) | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs751815417, COSV60656569; called by muse, mutect2, varscan2
- NAV3 | c.6848G>A p.R2283H (on ENST00000397909 / NM_001024383.2; = p.R2261H on NM_014903.6) | Missense Mutation (SNP) | VAF 135/295 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758160570; called by muse, mutect2, varscan2
- NBPF12 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 193/374 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1343726720; called by muse, mutect2, varscan2
- NCKAP5L | c.3926G>C p.G1309A | Missense Mutation (SNP) | VAF 324/671 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60129176; called by muse, mutect2, varscan2
- NCOR1 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1406850631, COSV51964364; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 166/360 reads (46%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs200513188; called by muse, mutect2, varscan2
- NFKBIB | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs746214449; called by muse, mutect2, varscan2
- NGRN | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 171/541 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1193439022; called by muse, mutect2, varscan2
- NISCH | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1344315704, COSV100617631; called by muse, mutect2, varscan2
- NLRP1 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 213/387 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs750702976; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 54/473 reads (11%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NOX3 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 166/347 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50156274; called by muse, mutect2, varscan2
- NPAS4 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 198/414 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1430096101, COSV60652325; called by muse, mutect2, varscan2
- NPC1L1 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 241/511 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs778913010, COSV99206087; called by muse, mutect2, varscan2
- NPFFR1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 90/750 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1191374740; called by muse, mutect2, varscan2
- NPW | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 286/582 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as rs1371540489; called by muse, mutect2, varscan2
- NR1H2 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 314/702 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1175038242; called by muse, mutect2, varscan2
- NR2C2AP | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.179); catalogued as rs777174194, COSV100284449; called by muse, mutect2, varscan2
- NR2F1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776020140, COSV59067477, COSV59068187; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 200/421 reads (48%) | catalogued as rs776154715; called by mutect2, varscan2
- NRK | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs760958200; called by muse, mutect2, varscan2
- NTSR2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 82/754 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs773295062, COSV100183939; called by muse, mutect2, varscan2
- NUMBL | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 75/492 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1234577930; called by muse, mutect2, varscan2
- NUP205 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 183/404 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs997385891, COSV53658239, COSV53659887; called by muse, mutect2, varscan2
- OBSCN | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 37/681 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as rs1226153147; called by muse, mutect2
- OPLAH | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 333/660 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs575947480, COSV101470788; called by muse, mutect2, varscan2
- OPTC | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 231/471 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs150633473, COSV65867446; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 73/516 reads (14%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- OR2B6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376301628; called by muse, mutect2, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 195/474 reads (41%) | catalogued as COSV57137289; called by mutect2, pindel, varscan2
- OR51D1 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 286/573 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1360024456; called by muse, mutect2, varscan2
- OR51S1 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 221/443 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59057989; called by muse, mutect2, varscan2
- OR5C1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 409/735 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374146289, COSV65456046; called by muse, mutect2, varscan2
- OR6B1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 267/552 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200541258; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 146/287 reads (51%) | catalogued as rs746200712; called by mutect2, varscan2
- OR6K6 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV63743816; called by muse, mutect2
- OR8J3 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 242/497 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879310; called by muse, mutect2, varscan2
- OSBP | c.2333C>A p.P778H | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374098760; called by muse, mutect2, varscan2
- P2RX3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 248/495 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs201667208; called by muse, mutect2, varscan2
- P2RX4 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.141); catalogued as COSV100078734; called by muse, mutect2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 107/262 reads (41%) | catalogued as rs763394045; called by mutect2, varscan2
- PALMD | c.1036dup p.R346Kfs*35 | Frame Shift Ins (INS) | VAF 236/597 reads (40%) | catalogued as rs1404233567; called by mutect2, pindel, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 309/322 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- PCDH7 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 190/661 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199625330; called by muse, mutect2, varscan2
- PCDH8 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 257/1118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746315269; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 386/765 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PCDHGA8 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 273/546 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); catalogued as rs762034418; called by muse, mutect2, varscan2
- PCDHGB1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 345/782 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99536286; called by muse, mutect2, varscan2
- PCSK4 | c.1874dup p.R626Afs*71 | Frame Shift Ins (INS) | VAF 320/736 reads (43%) | catalogued as rs1174914612; called by mutect2, pindel, varscan2
- PDE4D | c.487C>T p.R163W (on ENST00000340635 / NM_001104631.2; = p.R27W on NM_006203.4) | Missense Mutation (SNP) | VAF 158/308 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749395945, COSV58969110; called by muse, mutect2, varscan2
- PDZD8 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771181712, COSV53693938; called by muse, mutect2, varscan2
- PERM1 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 344/713 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV58023799; called by muse, mutect2, varscan2
- PHACTR4 | c.1037dup p.L347Tfs*18 (on ENST00000373839 / NM_001350159.2; = p.L357Tfs*18 on NM_023923.4) | Frame Shift Ins (INS) | VAF 233/498 reads (47%) | catalogued as rs776036043; called by mutect2, varscan2
- PHF20L1 | c.1721del p.K574Rfs*28 | Frame Shift Del (DEL) | VAF 24/198 reads (12%) | catalogued as rs772333737; called by mutect2, varscan2
- PHF3 | c.6028C>T p.R2010* | Nonsense Mutation (SNP) | VAF 225/461 reads (49%) | catalogued as rs746217827; called by muse, mutect2, varscan2
- PHF7 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 136/372 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs372765636; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 113/432 reads (26%) | catalogued as rs748850271; called by pindel, varscan2
- PI4KA | c.5656G>A p.V1886M | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338698528, COSV55423391; called by muse, mutect2
- PIGV | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 211/412 reads (51%) | catalogued as rs770220740, CM145505; called by muse, mutect2, varscan2
- PKN2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs755439353; called by muse, mutect2, varscan2
- PLXNA1 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs749976520; called by muse, mutect2, varscan2
- PLXNA4 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 37/750 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1003358330, COSV58139896; called by muse, mutect2
- PNMA8B | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 38/818 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs1166689466, COSV66537462; called by muse, mutect2
- POC5 | c.344A>G p.H115R (on ENST00000428202 / NM_001099271.2; = p.H90R on NM_152408.2) | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs751969329, COSV100994298; called by muse, mutect2, varscan2
- POLR1A | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 203/399 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs570647558; called by muse, mutect2, varscan2
- POLR2A | c.21del p.S8Rfs*19 | Frame Shift Del (DEL) | VAF 204/563 reads (36%) | catalogued as rs762376289; called by mutect2, pindel, varscan2
- POLRMT | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 152/490 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1393596779, COSV52113683; called by muse, mutect2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 121/383 reads (32%) | catalogued as rs1056475720, COSV52881818; called by mutect2, pindel, varscan2
- PPP6R2 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs751823681; called by muse, mutect2, varscan2
- PRDM16 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 270/598 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs377688111; called by muse, mutect2, varscan2
- PRR35 | c.787del p.R263Afs*40 | Frame Shift Del (DEL) | VAF 128/438 reads (29%) | catalogued as COSV53462712; called by mutect2, pindel, varscan2
- PSG3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384469320, COSV100549214; called by muse, mutect2, varscan2
- PTPN23 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200695676, COSV55546114; called by muse, mutect2, varscan2
- PXDN | c.2240C>T p.T747I | Missense Mutation (SNP) | VAF 241/513 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53245778; called by muse, mutect2, varscan2
- PXDN | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 249/510 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1558496208, COSV99414516; called by muse, mutect2, varscan2
- PXK | c.1375del p.R459Efs*4 | Frame Shift Del (DEL) | VAF 146/296 reads (49%) | catalogued as rs751548577; called by mutect2, varscan2
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 156/338 reads (46%) | catalogued as rs752866106; called by mutect2, varscan2
- RAP1GAP2 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 257/529 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1260592197, COSV54585190; called by muse, mutect2, varscan2
- RASGRP3 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 119/234 reads (51%) | catalogued as COSV67824589; called by muse, mutect2, varscan2
- RERE | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 280/874 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs557677362; called by muse, mutect2, varscan2
- RICTOR | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as rs759467094; called by muse, mutect2, varscan2
- RIOK2 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 108/357 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs200136201; called by muse, mutect2, varscan2
- RND3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 70/588 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs777749153; called by muse, mutect2, varscan2
- RNF213 | c.3944C>T p.T1315M | Missense Mutation (SNP) | VAF 115/332 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs149676075; called by muse, mutect2, varscan2
- RNF44 | c.577del p.Q193Sfs*80 | Frame Shift Del (DEL) | VAF 163/372 reads (44%) | catalogued as rs748776013; called by mutect2, pindel, varscan2
- RNFT2 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 219/644 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1230838629; called by muse, mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 176/473 reads (37%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- ROM1 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 164/524 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV53881417; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 150/356 reads (42%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS9 | c.278A>C p.K93T | Missense Mutation (SNP) | VAF 227/803 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV57189986; called by muse, mutect2, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 122/431 reads (28%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RSPO4 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 190/383 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs370469988; called by muse, mutect2, varscan2
- RUNDC3B | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 220/413 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55949445, COSV55961291; called by muse, mutect2, varscan2
- RYR3 | c.8699C>T p.A2900V (on ENST00000389232; = p.A2901V on NM_001036.6) | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as rs1400117455, COSV66778488; called by muse, mutect2, varscan2
- S100A8 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 178/477 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); catalogued as rs372026567; called by muse, mutect2, varscan2
- S1PR1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 156/495 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513111; called by muse, mutect2, varscan2
- SALL3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 86/786 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1433758208; called by muse, varscan2
- SALL3 | c.3440G>A p.G1147D | Missense Mutation (SNP) | VAF 313/623 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs747460032; called by muse, mutect2, varscan2
- SAMD11 | c.1237dup p.Q413Pfs*42 | Frame Shift Ins (INS) | VAF 84/665 reads (13%) | catalogued as rs1223597129; called by mutect2, varscan2
- SART3 | c.2618C>T p.S873L (on ENST00000228284; = p.S855L on NM_014706.4) | Missense Mutation (SNP) | VAF 185/369 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs146354825; called by muse, mutect2, varscan2
- SBF2 | c.2522A>G p.H841R | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751504575; called by muse, varscan2
- SBSN | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 164/664 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as COSV71733355; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 44/308 reads (14%) | catalogued as rs757259031; called by mutect2, varscan2
- SCN1A | c.5510C>T p.P1837L (on ENST00000303395 / NM_001202435.3; = p.P1826L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/384 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs149225252, COSV57669951; ClinVar: uncertain significance; called by muse, varscan2
- SCN3A | c.4961C>T p.A1654V | Missense Mutation (SNP) | VAF 284/604 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51801173; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 133/369 reads (36%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SEC16A | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 170/397 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs773116220; called by muse, mutect2, varscan2
- SEC23A | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 182/358 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs749527149; called by muse, mutect2, varscan2
- SEC62 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 143/258 reads (55%) | catalogued as COSV61260942; called by muse, mutect2, varscan2
- SEL1L2 | c.789del p.V264* | Frame Shift Del (DEL) | VAF 96/378 reads (25%) | catalogued as COSV53151693; called by mutect2, pindel, varscan2
- SELENOM | c.140dup p.Sec48Mfs*34 | Frame Shift Ins (INS) | VAF 193/535 reads (36%) | catalogued as rs753938731; called by mutect2, pindel, varscan2
- SEMA4D | c.1963G>C p.A655P | Missense Mutation (SNP) | VAF 365/640 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs986840497; called by muse, mutect2, varscan2
- SENP6 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs868139662, COSV104402205; called by muse, mutect2
- SEPTIN8 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as rs962313831; called by muse, varscan2
- SERPINA1 | c.918G>A p.R306= | Splice Region (SNP) | VAF 180/347 reads (52%) | catalogued as rs759132932; called by muse, mutect2, varscan2
- SFSWAP | c.661A>G p.R221G | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs747983999; called by muse, mutect2, varscan2
- SH2D7 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 203/431 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs74466400; called by muse, mutect2, varscan2
- SH3BGRL2 | c.249del p.F83Lfs*13 | Frame Shift Del (DEL) | VAF 156/362 reads (43%) | catalogued as COSV63965661; called by mutect2, pindel, varscan2
- SH3RF1 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as rs1317835155; called by muse, mutect2, varscan2
- SIGLEC9 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 277/608 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750378417; called by muse, mutect2, varscan2
- SIPA1L3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 79/604 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99729181; called by muse, mutect2, varscan2
- SKIV2L | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 226/427 reads (53%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.761); catalogued as rs774644201, COSV61713745; called by muse, mutect2, varscan2
- SKOR1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 268/543 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58244651; called by muse, mutect2, varscan2
- SLC22A10 | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 52/486 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1053449979; called by muse, mutect2
- SLC22A4 | c.1520del p.F507Sfs*7 | Frame Shift Del (DEL) | VAF 135/439 reads (31%) | catalogued as rs72552721; called by mutect2, pindel, varscan2
- SLC25A22 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 232/448 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1332876414; called by muse, mutect2, varscan2
- SLC26A1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 278/750 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs750594086; called by muse, mutect2
- SLC29A3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 77/700 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs368939297; called by muse, mutect2, varscan2
- SLC38A10 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 228/597 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs775182432, COSV66101390; called by muse, mutect2, varscan2
- SLC44A3 | c.278del p.K93Nfs*6 (on ENST00000271227 / NM_001114106.3; = p.K45Nfs*6 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 92/261 reads (35%) | catalogued as rs748117099; called by mutect2, pindel, varscan2
- SLC4A5 | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs770652020, COSV61035171; called by muse, mutect2, varscan2
- SLF2 | c.2360del p.L787* | Frame Shift Del (DEL) | VAF 139/352 reads (39%) | catalogued as rs1007972651, COSV53275602; called by mutect2, pindel, varscan2
- SMC6 | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.351); catalogued as rs751723798, COSV61172952; called by muse, mutect2, varscan2
- SNX9 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV101093877, COSV67585228; called by muse, mutect2, varscan2
- SORCS1 | c.214del p.L72Sfs*2 | Frame Shift Del (DEL) | VAF 344/870 reads (40%) | catalogued as COSV99545196; called by mutect2, pindel, varscan2
- SOX12 | c.381del p.G128Vfs*171 | Frame Shift Del (DEL) | VAF 329/783 reads (42%) | catalogued as rs1345087091; called by mutect2, pindel, varscan2
- SOX13 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 73/546 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs768271282, COSV65826546; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 162/368 reads (44%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPI1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 300/651 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs1370001180; called by muse, mutect2, varscan2
- SPINK5 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 53/365 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.401); catalogued as rs761323454; called by muse, mutect2, varscan2
- SPSB1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 347/691 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296370694, COSV100049755; called by muse, mutect2, varscan2
- SRSF1 | c.158del p.G53Dfs*85 | Frame Shift Del (DEL) | VAF 268/630 reads (43%) | catalogued as COSV51964296, COSV51965809; called by mutect2, pindel, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 162/350 reads (46%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD9 | c.8057C>T p.A2686V | Missense Mutation (SNP) | VAF 261/488 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1354619556; called by muse, mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 50/358 reads (14%) | catalogued as rs746501298; called by mutect2, varscan2
- SVIL | c.5821G>A p.A1941T (on ENST00000355867 / NM_021738.3; = p.A1515T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs767857736; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 105/196 reads (54%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNPO2 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 154/547 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1319671253; called by muse, mutect2, varscan2
- SYT16 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 241/498 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777540095, COSV70856141; called by muse, mutect2, varscan2
- TADA2B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 281/546 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs771996154, COSV53828195; called by muse, varscan2
- TAF5 | c.1669T>C p.Y557H | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs757728240; called by muse, mutect2, varscan2
- TARM1 | c.340del p.H114Tfs*14 (on ENST00000616041 / NM_001330650.1; = p.H106Tfs*14 on NM_001135686.3) | Frame Shift Del (DEL) | VAF 286/704 reads (41%) | catalogued as rs773860043; called by mutect2, pindel, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 194/390 reads (50%) | catalogued as rs753101364; called by mutect2, varscan2
- TBX4 | c.143del p.P48Rfs*40 | Frame Shift Del (DEL) | VAF 44/475 reads (9%) | catalogued as rs1414958198; called by mutect2, pindel
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 192/387 reads (50%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 296/894 reads (33%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TCF3 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 126/299 reads (42%) | catalogued as rs746665695, COSV53645113; called by muse, mutect2, varscan2
- TCF7 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 30/484 reads (6%) | catalogued as COSV100389973; called by muse, mutect2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 226/559 reads (40%) | catalogued as rs778855667; called by mutect2, pindel, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 115/230 reads (50%) | catalogued as rs745872748; called by mutect2, varscan2
- TDO2 | c.686del p.N229Ifs*11 | Frame Shift Del (DEL) | VAF 119/385 reads (31%) | catalogued as rs1291985502; called by mutect2, pindel, varscan2
- TDRD6 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 333/645 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1351763540, COSV60177012; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 138/347 reads (40%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs769195365, COSV65785547; called by muse, mutect2, varscan2
- TESPA1 | c.426del p.T143Pfs*59 (on ENST00000316577 / NM_001098815.3; = p.T5Pfs*59 on NM_014796.2 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 149/357 reads (42%) | catalogued as rs1365960762; called by mutect2, pindel, varscan2
- TFB1M | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1285039243; called by muse, mutect2, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 106/243 reads (44%) | catalogued as rs745348876; called by mutect2, varscan2
- THRA | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 30/630 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV52845465; called by muse, mutect2
- THRAP3 | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 47/143 reads (33%) | catalogued as COSV63567426; called by muse, mutect2, varscan2
- TIMP1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs1476457782, COSV54483887; called by muse, mutect2, varscan2
- TINAG | c.564del p.F188Lfs*15 | Frame Shift Del (DEL) | VAF 56/490 reads (11%) | catalogued as rs1336975370; called by mutect2, pindel, varscan2
- TIPIN | c.681T>C p.N227= | Splice Region (SNP) | VAF 75/239 reads (31%) | catalogued as rs1214970390; called by muse, mutect2, varscan2
- TM6SF1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 173/340 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs202192905, COSV51944502; called by muse, mutect2, varscan2
- TMEM196 | c.192dup p.S65Ifs*68 | Frame Shift Ins (INS) | VAF 126/270 reads (47%) | catalogued as rs759398828; called by mutect2, varscan2
- TMEM232 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs978515165; called by muse, mutect2, varscan2
- TMEM74 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs553258535, COSV99865796; called by muse, mutect2
- TMPO | c.295dup p.T99Nfs*2 | Frame Shift Ins (INS) | VAF 108/218 reads (50%) | catalogued as rs770800449; called by mutect2, varscan2
- TNPO1 | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV61523766; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 134/592 reads (23%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNS1 | c.4750G>A p.G1584S | Missense Mutation (SNP) | VAF 205/421 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs371630425, COSV50745723; called by muse, mutect2, varscan2
- TNS3 | c.4159G>T p.D1387Y | Missense Mutation (SNP) | VAF 174/356 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234977; called by muse, mutect2, varscan2
- TP53I11 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 175/480 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758479755; called by muse, mutect2, varscan2
- TPR | c.2052dup p.E685Rfs*6 | Frame Shift Ins (INS) | VAF 127/321 reads (40%) | catalogued as rs1432981657; called by mutect2, pindel, varscan2
- TRAF6 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 48/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs548543739, COSV61922473; called by muse, mutect2
- TRDV2 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 130/245 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1223618670; called by muse, mutect2, varscan2
- TRIM58 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 220/434 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs954995992, COSV63570116; called by muse, mutect2, varscan2
- TRIO | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs139892017; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 74/268 reads (28%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIP12 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 167/223 reads (75%) | catalogued as COSV99390312; called by muse, mutect2, varscan2
- TRPC1 | c.1364G>A p.R455H (on ENST00000476941 / NM_001251845.2; = p.R421H on NM_003304.4) | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs780499678; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 117/263 reads (44%) | catalogued as COSV60250864; called by mutect2, pindel, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 242/586 reads (41%) | catalogued as rs762935066, COSV55967995; called by mutect2, pindel, varscan2
- TRPM5 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772292156, COSV50144391; called by muse, mutect2, varscan2
- TRPV2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 194/612 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs536622113, COSV58428676; called by muse, mutect2, varscan2
- TRRAP | c.5527G>A p.A1843T (on ENST00000359863 / NM_001244580.1; = p.A1825T on NM_003496.3) | Missense Mutation (SNP) | VAF 218/584 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781849870, COSV62839104; called by muse, mutect2, varscan2
- TTLL7 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 208/392 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775482319, COSV53083252; called by muse, varscan2
- TTN | c.35685del p.K11895Nfs*2 (on ENST00000591111; = p.K4471Nfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 58/250 reads (23%) | catalogued as rs1284446305; called by mutect2, pindel, varscan2
- TUBG2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as rs1303963861, COSV52219653; called by muse, mutect2, varscan2
- TUT4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV57111734; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 140/266 reads (53%) | catalogued as rs760251146; called by mutect2, varscan2
- TYK2 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 255/556 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53385611; called by muse, mutect2, varscan2
- UAP1L1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 351/653 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs530235633; called by muse, mutect2, varscan2
- UBTF | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1309107358, COSV57185187; called by muse, mutect2, varscan2
- UGT1A6 | c.1560del p.R522Efs*22 | Frame Shift Del (DEL) | VAF 186/464 reads (40%) | catalogued as COSV59381895; called by mutect2, pindel, varscan2
- UPF2 | c.284del p.K95Rfs*27 | Frame Shift Del (DEL) | VAF 57/484 reads (12%) | catalogued as rs1564374891; called by mutect2, pindel, varscan2
- URB1 | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 159/357 reads (45%) | catalogued as rs189942230; called by muse, mutect2, varscan2
- USF1 | c.389del p.G130Vfs*33 | Frame Shift Del (DEL) | VAF 166/586 reads (28%) | catalogued as rs1374448785; called by mutect2, pindel, varscan2
- USF3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 210/434 reads (48%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs965721326; called by muse, mutect2, varscan2
- USP49 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 106/738 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs781750759; called by muse, mutect2, varscan2
- UTP14C | c.71dup p.N24Kfs*6 | Frame Shift Ins (INS) | VAF 403/764 reads (53%) | catalogued as rs769669893; called by mutect2, pindel, varscan2
- VCAN | c.9361G>A p.G3121R | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314929549, COSV54108796, COSV99424537; called by muse, mutect2, varscan2
- VIRMA | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs781536712, COSV52585122; called by muse, mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 141/312 reads (45%) | catalogued as rs1554609756; called by mutect2, pindel, varscan2
- VPS39 | c.2092C>T p.R698C (on ENST00000348544 / NM_001301138.2; = p.R687C on NM_015289.5) | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780746454, COSV58793409; called by muse, mutect2, varscan2
- VPS51 | c.73del p.E25Rfs*13 | Frame Shift Del (DEL) | VAF 202/559 reads (36%) | catalogued as rs1215813683, COSV99661065; called by mutect2, varscan2
- VSX2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 338/662 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as rs781547325; called by muse, mutect2, varscan2
- VWDE | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs373987215; called by muse, mutect2, varscan2
- WDFY4 | c.8114G>A p.C2705Y | Missense Mutation (SNP) | VAF 106/349 reads (30%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.689); catalogued as rs1449140826; called by muse, mutect2, varscan2
- WFS1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 307/628 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs756667462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WHRN | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 284/789 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1347510206; called by muse, mutect2, varscan2
- WIZ | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1434707651, COSV99652624; called by muse, mutect2, varscan2
- WNK2 | c.2756T>C p.M919T | Missense Mutation (SNP) | VAF 36/852 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1444633564; called by muse, mutect2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 120/421 reads (29%) | catalogued as rs762052135; called by mutect2, varscan2
- XRN1 | c.2012dup p.L671Ffs*30 | Frame Shift Ins (INS) | VAF 132/263 reads (50%) | catalogued as rs1197134126; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 319/752 reads (42%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 42/306 reads (14%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZBTB2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 275/551 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1220876263; called by muse, mutect2, varscan2
- ZBTB7A | c.674del p.P225Rfs*99 | Frame Shift Del (DEL) | VAF 322/829 reads (39%) | catalogued as rs1555693029; called by mutect2, pindel, varscan2
- ZC3H12A | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444428485; called by muse, mutect2, varscan2
- ZC3H12C | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584549; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 52/450 reads (12%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H4 | c.3110G>A p.G1037D | Missense Mutation (SNP) | VAF 95/663 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as rs767461623; called by muse, mutect2, varscan2
- ZFHX3 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 218/492 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51717973, COSV51725973, COSV51733095; called by muse, mutect2, varscan2
- ZFHX4 | c.8707A>G p.S2903G | Missense Mutation (SNP) | VAF 231/434 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50493593; called by muse, mutect2, varscan2
- ZIM3 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 183/438 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs531319362; called by muse, mutect2, varscan2
- ZMIZ2 | c.2340del p.I781Sfs*12 | Frame Shift Del (DEL) | VAF 124/447 reads (28%) | catalogued as rs1279929143; called by mutect2, pindel, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 220/332 reads (66%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYND11 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV59077138; called by muse, mutect2
- ZNF133 | c.195del p.K65Nfs*122 (on ENST00000316358 / NM_001352454.2; = p.K65Nfs*121 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 94/298 reads (32%) | catalogued as rs753775995, COSV60366352; called by mutect2, varscan2
- ZNF319 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 100/724 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.36); catalogued as COSV54624329; called by muse, mutect2, varscan2
- ZNF454 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 268/542 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs774761220; called by muse, mutect2, varscan2
- ZNF467 | c.1758dup p.E587Rfs*134 | Frame Shift Ins (INS) | VAF 308/763 reads (40%) | catalogued as rs1178444108; called by mutect2, pindel, varscan2
- ZNF469 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 288/647 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs568820656, COSV71259343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 78/630 reads (12%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF536 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 395/797 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.73); catalogued as rs762428720, COSV99052767; called by muse, mutect2, varscan2
- ZNF563 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 200/543 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs757525963; called by muse, mutect2, varscan2
- ZNF638 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV52482690; called by muse, mutect2, varscan2
- ZNF646 | c.3976T>C p.Y1326H | Missense Mutation (SNP) | VAF 29/717 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54926775; called by muse, mutect2
- ZNF648 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 158/668 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754881990, COSV60569527; called by muse, varscan2
- ZNF648 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 360/676 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs770207027, COSV60570619; called by muse, varscan2
- ZNF653 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1247589333; called by muse, mutect2, varscan2
- ZNF668 | c.1543dup p.Q515Pfs*41 | Frame Shift Ins (INS) | VAF 195/528 reads (37%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF688 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 234/582 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1355817208; called by muse, mutect2, varscan2
- ZNF705G | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 152/597 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs766462797; called by muse, varscan2
- ZNF71 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 333/674 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60146866; called by muse, mutect2, varscan2
- ZNF737 | c.513dup p.P172Tfs*12 | Frame Shift Ins (INS) | VAF 88/202 reads (44%) | catalogued as rs782545661; called by mutect2, varscan2
- ZNF763 | c.842del p.G281Efs*117 (on ENST00000358987 / NM_001367172.2; = p.G284Efs*117 on NM_001012753.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 260/629 reads (41%) | catalogued as COSV59689278; called by mutect2, pindel, varscan2
- ZNF90 | c.513del p.K171Nfs*6 | Frame Shift Del (DEL) | VAF 165/420 reads (39%) | catalogued as rs782729171; called by mutect2, pindel, varscan2
- ABCA5 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- ABCC10 | c.2078A>G p.Q693R (on ENST00000372530 / NM_001198934.2; = p.Q665R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/499 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC11 | c.630del p.L211Sfs*5 | Frame Shift Del (DEL) | VAF 207/538 reads (38%) | called by mutect2, pindel, varscan2
- ABCC2 | c.2822A>G p.E941G | Missense Mutation (SNP) | VAF 200/421 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCF2 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 64/516 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABHD14B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 302/568 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABHD8 | c.54del p.N19Tfs*18 | Frame Shift Del (DEL) | VAF 262/612 reads (43%) | called by mutect2, pindel
- AC008878.3 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 39/442 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2
- AC131160.1 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 117/217 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ACAA2 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 51/491 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ACIN1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 256/619 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACOT1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 263/552 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSM6 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 63/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACTL6B | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACTL7B | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 315/753 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ACTR8 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACVR2B | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAD2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 426/813 reads (52%) | called by muse, mutect2, varscan2
- ADGRL2 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- AFDN | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 291/595 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AFF1 | c.3201dup p.D1068Rfs*11 | Frame Shift Ins (INS) | VAF 96/368 reads (26%) | called by pindel, varscan2
- AGR2 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 258/502 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- AKAP12 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 248/493 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKAP13 | c.3113A>G p.N1038S | Missense Mutation (SNP) | VAF 248/547 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP13 | c.8141C>A p.S2714Y (on ENST00000394518 / NM_007200.5; = p.S2718Y on NM_006738.6) | Missense Mutation (SNP) | VAF 260/499 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ALPK2 | c.3604dup p.E1202Gfs*15 | Frame Shift Ins (INS) | VAF 62/507 reads (12%) | called by mutect2, pindel, varscan2
- AMD1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ANGPTL2 | c.654del p.A219Lfs*30 | Frame Shift Del (DEL) | VAF 242/566 reads (43%) | called by mutect2, varscan2
- ANK1 | c.4849T>C p.S1617P | Missense Mutation (SNP) | VAF 28/638 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ANKEF1 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANKFY1 | c.2505A>T p.R835S (on ENST00000341657 / NM_001330063.2; = p.R836S on NM_016376.5) | Missense Mutation (SNP) | VAF 233/503 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ANKRD11 | c.4563G>T p.E1521D | Missense Mutation (SNP) | VAF 31/713 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ANKRD17 | c.7679A>G p.H2560R | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANKRD29 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 167/329 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ANO8 | c.3493del p.R1165Afs*154 | Frame Shift Del (DEL) | VAF 108/256 reads (42%) | called by mutect2, pindel, varscan2
- ANO9 | c.1433T>C p.M478T | Missense Mutation (SNP) | VAF 210/461 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- AP1G1 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 190/384 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, varscan2
- AP5M1 | c.443del p.N148Mfs*5 | Frame Shift Del (DEL) | VAF 50/446 reads (11%) | called by mutect2, pindel, varscan2
- AP5Z1 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 192/662 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- APC2 | c.5462del p.P1821Lfs*35 | Frame Shift Del (DEL) | VAF 85/764 reads (11%) | called by mutect2, pindel, varscan2
- APC2 | c.6689T>C p.V2230A | Missense Mutation (SNP) | VAF 321/783 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AREL1 | c.1307C>A p.S436Y | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARFGEF3 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP42 | c.575del p.K192Rfs*55 | Frame Shift Del (DEL) | VAF 52/244 reads (21%) | called by pindel, varscan2
- ARHGEF10L | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 182/382 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ARID5B | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 220/470 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ARMC8 | c.1792_1794del p.D598del (on ENST00000469044 / NM_001363941.2; = p.D584del on NM_015396.6) | In Frame Del (DEL) | VAF 104/278 reads (37%) | called by pindel, varscan2
- ARPP21 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 134/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARRDC1 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 256/588 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB16 | c.1313del p.P438Rfs*53 | Frame Shift Del (DEL) | VAF 252/632 reads (40%) | called by mutect2, pindel, varscan2
- ASTE1 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN1 | c.1948dup p.V650Gfs*12 | Frame Shift Ins (INS) | VAF 143/516 reads (28%) | called by mutect2, pindel, varscan2
- ASTN2 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); called by muse, mutect2
- ATF6 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, varscan2
- ATOH8 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 369/745 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATP2B4 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 142/415 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATP6V1FNB | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 243/477 reads (51%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- B3GALNT1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 205/447 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAHCC1 | c.5313del p.S1772Afs*66 | Frame Shift Del (DEL) | VAF 105/803 reads (13%) | called by mutect2, pindel, varscan2
- BBC3 | c.247del p.R83Afs*146 (on ENST00000449228 / NM_001127240.3; = p.A49Pfs*166 on NM_014417.5) | Frame Shift Del (DEL) | VAF 190/468 reads (41%) | called by mutect2, pindel, varscan2
- BCAR3 | c.2120T>C p.V707A | Missense Mutation (SNP) | VAF 158/325 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, varscan2
- BCL9L | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 258/534 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BCR | c.3796C>A p.L1266M | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BDP1 | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 203/640 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- BEND4 | c.93dup p.S32Qfs*122 | Frame Shift Ins (INS) | VAF 201/505 reads (40%) | called by mutect2, pindel, varscan2
- BICDL2 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 294/589 reads (50%) | called by muse, mutect2, varscan2
- BMP4 | c.102del p.V35Sfs*83 | Frame Shift Del (DEL) | VAF 208/516 reads (40%) | called by mutect2, pindel, varscan2
- BPIFB3 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 194/398 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRIX1 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BTG3 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 219/466 reads (47%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 144/286 reads (50%) | called by mutect2, varscan2
- C10orf105 | c.106del p.L36Sfs*21 | Frame Shift Del (DEL) | VAF 331/771 reads (43%) | called by mutect2, pindel, varscan2
- C10orf67 | c.23G>A p.R8K (on ENST00000323327; = p.R9K on NM_153714.3) | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf22 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, varscan2
- CABLES1 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1G | c.4181G>A p.R1394Q | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAD | c.5437C>T p.P1813S | Missense Mutation (SNP) | VAF 201/374 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALCOCO1 | c.1222T>C p.W408R | Missense Mutation (SNP) | VAF 118/423 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMK1D | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 179/323 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMTA2 | c.842dup p.E282Rfs*29 | Frame Shift Ins (INS) | VAF 195/521 reads (37%) | called by mutect2, pindel, varscan2
- CC2D1B | c.2546A>C p.N849T | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CCDC138 | c.852del p.K284Nfs*3 | Frame Shift Del (DEL) | VAF 86/176 reads (49%) | called by mutect2, varscan2
- CCDC168 | c.10019C>T p.A3340V | Missense Mutation (SNP) | VAF 381/565 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC33 | c.1561_1563del p.K521del | In Frame Del (DEL) | VAF 155/315 reads (49%) | called by mutect2, pindel, varscan2
- CCDC88C | c.81del p.F27Lfs*9 | Frame Shift Del (DEL) | VAF 36/316 reads (11%) | called by mutect2, pindel, varscan2
- CCDC92 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 46/683 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- CCNB3 | c.1452del p.T485Pfs*5 | Frame Shift Del (DEL) | VAF 30/352 reads (9%) | called by mutect2, pindel
- CCNE1 | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCT6A | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, varscan2
- CD1E | c.901dup p.W301Lfs*26 | Frame Shift Ins (INS) | VAF 35/321 reads (11%) | called by mutect2, pindel, varscan2
- CDH18 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 133/372 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CDK11B | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 162/461 reads (35%) | called by pindel, varscan2
- CDK16 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CDK8 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 86/954 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- CELSR3 | c.1392del p.N465Tfs*69 | Frame Shift Del (DEL) | VAF 331/817 reads (41%) | called by mutect2, pindel, varscan2
- CENPF | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 120/427 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CEP170 | c.3743A>C p.N1248T | Missense Mutation (SNP) | VAF 42/587 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CEP295 | c.1020T>G p.D340E | Missense Mutation (SNP) | VAF 168/445 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CFAP58 | c.1333T>A p.Y445N | Missense Mutation (SNP) | VAF 26/419 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CFAP97D2 | c.303del p.K102Rfs*33 | Frame Shift Del (DEL) | VAF 162/559 reads (29%) | called by mutect2, pindel, varscan2
- CFHR4 | c.629G>A p.C210Y (on ENST00000367416 / NM_001201551.2; = p.C211Y on NM_001201550.3) | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CGB7 | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHDH | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 273/585 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CHRM1 | c.800G>T p.R267M | Missense Mutation (SNP) | VAF 312/682 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CHRM1 | c.718A>G p.S240G | Missense Mutation (SNP) | VAF 360/773 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIZ1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 278/654 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLCN2 | c.1493del p.G498Afs*14 | Frame Shift Del (DEL) | VAF 175/391 reads (45%) | called by mutect2, pindel, varscan2
- CLDN15 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- CLEC17A | c.38del p.P13Hfs*107 | Frame Shift Del (DEL) | VAF 127/345 reads (37%) | called by mutect2, pindel, varscan2
- COL11A1 | c.4660dup p.T1554Nfs*6 | Frame Shift Ins (INS) | VAF 35/326 reads (11%) | called by mutect2, varscan2
- COL12A1 | c.6497T>C p.M2166T | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A3 | c.3927del p.G1310Afs*83 | Frame Shift Del (DEL) | VAF 278/516 reads (54%) | called by mutect2, varscan2
- COPB1 | c.1089A>C p.E363D | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- COPS7A | c.655del p.T219Pfs*21 | Frame Shift Del (DEL) | VAF 49/351 reads (14%) | called by mutect2, pindel, varscan2
- CPNE2 | c.269A>T p.K90M | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CPPED1 | c.826del p.H276Tfs*20 | Frame Shift Del (DEL) | VAF 237/578 reads (41%) | called by mutect2, pindel, varscan2
- CPSF4 | c.539del p.P180Hfs*24 | Frame Shift Del (DEL) | VAF 221/526 reads (42%) | called by mutect2, pindel, varscan2
- CR1L | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 303/586 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CRKL | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CRLF1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 183/397 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CRTC1 | c.535del p.R179Efs*5 | Frame Shift Del (DEL) | VAF 169/455 reads (37%) | called by mutect2, pindel, varscan2
- CSPG4 | c.5824A>G p.I1942V | Missense Mutation (SNP) | VAF 325/631 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTDP1 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 332/920 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CTNND1 | c.1265del p.K422Rfs*26 | Frame Shift Del (DEL) | VAF 194/504 reads (38%) | called by mutect2, pindel, varscan2
- CTPS2 | c.151del p.S51Hfs*11 | Frame Shift Del (DEL) | VAF 177/242 reads (73%) | called by mutect2, pindel, varscan2
- CUL2 | c.194del p.L65Wfs*54 | Frame Shift Del (DEL) | VAF 147/357 reads (41%) | called by mutect2, pindel, varscan2
- CWC22 | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 38/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CYP2A13 | c.495C>T p.G165= | Splice Region (SNP) | VAF 173/382 reads (45%) | called by muse, mutect2, varscan2
- CYP4F2 | c.703dup p.R235Kfs*4 | Frame Shift Ins (INS) | VAF 221/560 reads (39%) | called by mutect2, pindel, varscan2
- DAAM1 | c.3200G>A p.S1067N | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DARS2 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DCAF1 | c.186T>C p.P62= | Splice Region (SNP) | VAF 92/297 reads (31%) | called by muse, mutect2, varscan2
- DDX39A | c.496dup p.H166Pfs*17 | Frame Shift Ins (INS) | VAF 204/498 reads (41%) | called by mutect2, pindel, varscan2
- DENND4A | c.5263del p.S1755Vfs*10 | Frame Shift Del (DEL) | VAF 36/340 reads (11%) | called by mutect2, pindel
- DENND4A | c.3902A>G p.H1301R | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DENND4B | c.762del p.V255Cfs*44 | Frame Shift Del (DEL) | VAF 166/654 reads (25%) | called by mutect2, pindel, varscan2
- DGKG | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DHX38 | c.3047T>C p.L1016P | Missense Mutation (SNP) | VAF 224/499 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DIDO1 | c.3797del p.P1266Lfs*8 | Frame Shift Del (DEL) | VAF 202/661 reads (31%) | called by mutect2, pindel, varscan2
- DISP2 | c.3388C>A p.L1130M | Missense Mutation (SNP) | VAF 144/597 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DLG2 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 148/404 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAH7 | c.8951C>T p.A2984V | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DOCK10 | c.5342del p.L1781* | Frame Shift Del (DEL) | VAF 151/419 reads (36%) | called by pindel, varscan2
- DOP1B | c.1865G>A p.S622N | Missense Mutation (SNP) | VAF 256/500 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DSCAML1 | c.2333del p.P778Hfs*36 (on ENST00000321322; = p.P718Hfs*36 on NM_020693.4) | Frame Shift Del (DEL) | VAF 203/509 reads (40%) | called by mutect2, pindel, varscan2
- DSG1 | c.1700dup p.L567Ffs*6 | Frame Shift Ins (INS) | VAF 148/360 reads (41%) | called by mutect2, pindel, varscan2
- DTX4 | c.1222-1G>A p.X408_splice | Splice Site (SNP) | VAF 125/250 reads (50%) | called by muse, mutect2, varscan2
- EGFR | c.2805G>T p.Q935H | Missense Mutation (SNP) | VAF 138/424 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EIF4E3 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 129/298 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EIF4G2 | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 167/321 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAC2 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 133/374 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ELP1 | c.621dup p.A208Cfs*28 | Frame Shift Ins (INS) | VAF 172/448 reads (38%) | called by mutect2, pindel, varscan2
- EP300 | c.1640A>G p.N547S | Missense Mutation (SNP) | VAF 129/380 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EP400 | c.8659G>A p.A2887T | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPB41L2 | c.2114T>C p.I705T | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2
- EPPK1 | c.3893T>G p.L1298R | Missense Mutation (SNP) | VAF 95/682 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
854 further variants in this file (455 protein-altering or splice-affecting, 337 silent, 62 other) are not listed here.
